Somatic mutation profile of tumor specimen TCGA-B7-A5TI-01A (aliquot TCGA-B7-A5TI-01A-11D-A31L-08) from TCGA case TCGA-B7-A5TI, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.1 years (19,014 days).
Specimen TCGA-B7-A5TI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86ee309d-d44a-4933-b4e3-958f3013e5d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B7-A5TI-10A (Blood Derived Normal), aliquot TCGA-B7-A5TI-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbcb43e4-8946-4cbe-8860-1692a3775b7a

The open-access MAF lists 710 somatic variants for this specimen: 537 protein-altering or splice-affecting, 160 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 376, Silent 160, Frame Shift Del 102, Frame Shift Ins 21, Nonsense Mutation 21, In Frame Del 8, Intron 7, Splice Site 5, Splice Region 4, 3'UTR 3, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL10 | c.499del p.S167Lfs*6 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs387906350, COSV65354275; ClinVar: pathogenic; called by mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 13/21 reads (62%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MLH1 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs63751302, CM117315, COSV99212444; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 35/137 reads (26%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NOTCH1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1057523819, COSV53030190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 46/144 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121918568, CM081766, COSV100200884; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC63 | c.1605del p.K535Nfs*28 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs752868449; ClinVar: pathogenic; called by mutect2, varscan2
- SMPD1 | c.996del p.F333Sfs*52 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs387906289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | hotspot (GDC flag); catalogued as CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARD | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs765753582, COSV100991895; called by muse, mutect2, varscan2
- ABCA7 | c.3117G>T p.K1039N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99565740; called by muse, mutect2, varscan2
- ABCB1 | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs199931362, COSV55952252; called by muse, mutect2, varscan2
- ABCC8 | c.3551C>T p.A1184V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs137852675, CM072826, CM1411308, COSV56846628; called by muse, mutect2, varscan2
- ACAA2 | c.883G>C p.G295R | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99551833; called by muse, mutect2, varscan2
- ACAN | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs565318742, COSV61360056; called by muse, mutect2, varscan2
- ACE | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.639); catalogued as rs148018765; called by muse, mutect2, varscan2
- ACSS1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100053715; called by muse, mutect2, varscan2
- ACTR5 | c.1743G>C p.K581N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV99710012; called by muse, mutect2, varscan2
- ACVR1B | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV57777696; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 62/107 reads (58%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM18 | c.483G>T p.W161C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as COSV99695528; called by muse, mutect2, varscan2
- ADAM33 | c.2336C>A p.P779H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV100597668; called by muse, mutect2, varscan2
- ADAMTS17 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); catalogued as COSV51479194, COSV99170656; called by muse, mutect2, varscan2
- ADAMTS2 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99202059; called by muse, mutect2, varscan2
- ADAMTS7 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV101183098; called by muse, mutect2, varscan2
- ADGRA2 | c.1178del p.G393Vfs*40 | Frame Shift Del (DEL) | VAF 33/165 reads (20%) | catalogued as COSV104408572; called by mutect2, pindel, varscan2
- ADGRF3 | c.2510G>A p.R837Q (on ENST00000311519 / NM_001145168.1; = p.R638Q on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs367794085; called by muse, mutect2
- ADGRL2 | c.2035G>T p.G679* (on ENST00000370717 / NM_001366005.1; = p.G666* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 7/123 reads (6%) | catalogued as COSV99588967; called by muse, mutect2
- AHNAK2 | c.3950C>T p.A1317V | Missense Mutation (SNP) | VAF 124/259 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV100317446; called by muse, mutect2, varscan2
- AKAP17A | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs375125397, COSV100002218; called by muse, mutect2, varscan2
- AKR1A1 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.075); catalogued as rs759894468, COSV100698721; called by muse, mutect2, varscan2
- ALDH1L1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as rs754565747, COSV99856805; called by muse, mutect2, varscan2
- ALMS1 | c.1361A>G p.H454R | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as COSV100042414; called by muse, mutect2, varscan2
- ALMS1 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV100042419; called by muse, mutect2, varscan2
- AMPD2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as rs751988000, COSV56646182; called by muse, mutect2, varscan2
- ANKRD44 | c.2816del p.N939Ifs*16 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs1408961377; called by mutect2, pindel, varscan2
- ANXA8L1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1283615360; called by muse, mutect2, varscan2
- AP2A1 | c.386G>C p.C129S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as COSV100756264; called by muse, mutect2, varscan2
- AP4M1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs371712994; called by muse, mutect2, varscan2
- APBA1 | c.1885A>G p.K629E | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV99596047; called by muse, mutect2, varscan2
- APOE | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV99376096; called by muse, mutect2
- AQR | c.4126A>G p.T1376A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as rs755145206, COSV99333908; called by muse, mutect2, varscan2
- ARAP2 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.501); catalogued as COSV100394633, COSV58292870; called by muse, mutect2, varscan2
- ARHGAP24 | c.863T>C p.L288S (on ENST00000395184 / NM_001025616.3; = p.L195S on NM_031305.3) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982060; called by muse, mutect2, varscan2
- ARID1A | c.3977dup p.Q1327Afs*11 | Frame Shift Ins (INS) | VAF 33/119 reads (28%) | catalogued as COSV61376881; called by pindel, varscan2
- ASAP1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as rs745406996, COSV63044358, COSV63051230; called by muse, mutect2, varscan2
- ASAP3 | c.1376T>A p.L459H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100369428; called by muse, mutect2, varscan2
- ASIC5 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV101539741; called by muse, mutect2, varscan2
- ASMTL | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs374787639, COSV67243452; called by muse, mutect2, varscan2
- ATP2B1 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 129/435 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99665668; called by muse, mutect2, varscan2
- ATP6V1C2 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99695753; called by muse, mutect2, varscan2
- ATR | c.7784T>G p.I2595S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53818322, COSV99377946; called by muse, mutect2, varscan2
- ATRNL1 | c.3811C>T p.R1271* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV58086868; called by muse, mutect2, varscan2
- ATXN1 | c.719dup p.P241Tfs*70 | Frame Shift Ins (INS) | VAF 7/15 reads (47%) | catalogued as rs761436802; called by mutect2, varscan2
- AXIN1 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV99249767; called by muse, mutect2, varscan2
- AXL | c.874dup p.H292Pfs*47 | Frame Shift Ins (INS) | VAF 34/144 reads (24%) | catalogued as rs778012871; called by mutect2, varscan2
- B3GAT1 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as rs367583989, COSV100437896; called by muse, mutect2, varscan2
- BBS7 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs768945074, COSV52656799; called by muse, mutect2, varscan2
- BCAT2 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100302416; called by muse, mutect2, varscan2
- BCL2L1 | c.686T>A p.L229H (on ENST00000307677 / NM_001317919.2; = p.L166H on NM_001191.4) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100304683; called by muse, mutect2, varscan2
- BCL2L11 | c.457C>T p.R153W (on ENST00000393256 / NM_138621.5; = p.R93W on NM_006538.5) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146318804, COSV100427572; called by muse, mutect2, varscan2
- BNIP5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs139083096, COSV71325438; called by muse, mutect2, varscan2
- BTBD11 | c.3242A>G p.Q1081R (on ENST00000280758 / NM_001018072.2; = p.Q618R on NM_001017523.2) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV99775677; called by muse, mutect2, varscan2
- C16orf71 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs575594583, COSV54795717, COSV73918485; called by muse, mutect2, varscan2
- C1QTNF1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs758961252, COSV59263078; called by muse, mutect2, varscan2
- C2orf16 | c.4415G>T p.G1472V | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV100820792; called by muse, mutect2
- CA9 | c.767G>A p.S256N | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV100999820; called by muse, mutect2, varscan2
- CABLES2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 112/409 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs371230015; called by muse, mutect2, varscan2
- CAMKV | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV99615503; called by muse, varscan2
- CAMTA2 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV100772598; called by muse, mutect2, varscan2
- CAPSL | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368551299, COSV68438743; called by muse, mutect2, varscan2
- CASP8AP2 | c.1352T>C p.V451A | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs202104748; called by muse, mutect2, varscan2
- CCDC107 | c.840T>A p.S280R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as COSV100526228; called by muse, mutect2, varscan2
- CCDC18 | c.835_838del p.N279Vfs*22 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs757854064; called by pindel, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC39 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV99868738; called by muse, mutect2, varscan2
- CCDC40 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs760027732, COSV66474260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC93 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs754008225, COSV100098692; called by muse, mutect2, varscan2
- CCDC9B | c.294del p.M99Wfs*3 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | catalogued as rs765438623; called by mutect2, varscan2
- CCR1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.311); catalogued as rs773693739, COSV56123210, COSV99946804; called by muse, mutect2, varscan2
- CD109 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs1175385138, COSV54647173, COSV99753570; called by muse, mutect2, varscan2
- CDC14B | c.1493G>A p.R498H (on ENST00000375241 / NM_033331.4; = p.R459H on NM_003671.5) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs762273864, COSV55785021; called by muse, mutect2, varscan2
- CDC14B | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1257023062, COSV99685676; called by muse, mutect2, varscan2
- CDH1 | c.208del p.S70Pfs*13 | Frame Shift Del (DEL) | VAF 35/110 reads (32%) | catalogued as COSV55727943; called by mutect2, pindel, varscan2
- CDH11 | c.1184A>G p.N395S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1216298287, COSV99218313; called by muse, mutect2, varscan2
- CDNF | c.391dup p.T131Nfs*8 | Frame Shift Ins (INS) | VAF 30/125 reads (24%) | catalogued as rs773643595; called by mutect2, pindel, varscan2
- CELSR2 | c.3805G>A p.V1269I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs749003003, COSV99603776; called by muse, mutect2, varscan2
- CEP350 | c.7540C>T p.R2514* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV62599608; called by muse, mutect2, varscan2
- CFAP91 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs771319237, COSV56341376; called by muse, mutect2, varscan2
- CHST8 | c.1270T>C p.Y424H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.092); catalogued as COSV52856236, COSV99381074; called by muse, mutect2, varscan2
- CLCA2 | c.2670del p.N891Ifs*13 | Frame Shift Del (DEL) | VAF 74/345 reads (21%) | catalogued as rs768413031, COSV100991300; called by mutect2, pindel, varscan2
- CLCN1 | c.2509-1G>A p.X837_splice | Splice Site (SNP) | VAF 32/161 reads (20%) | catalogued as rs749952135, COSV58374073; called by muse, mutect2, varscan2
- CNOT6 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs748736531, COSV56159691, COSV99993491; called by muse, mutect2, varscan2
- COG1 | c.2665C>T p.R889W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144316008; called by muse, mutect2, varscan2
- COG7 | c.436-1G>T p.X146_splice | Splice Site (SNP) | VAF 23/71 reads (32%) | catalogued as COSV56153673; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs748995811; called by mutect2, varscan2
- COIL | c.485dup p.N162Kfs*6 | Frame Shift Ins (INS) | VAF 32/130 reads (25%) | catalogued as rs769265872; called by mutect2, varscan2
- COL17A1 | c.2209G>A p.G737R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs764552135, COSV62228647; called by muse, mutect2, varscan2
- COL1A1 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99867180; called by muse, mutect2, varscan2
- COL5A3 | c.3143del p.P1048Lfs*96 | Frame Shift Del (DEL) | VAF 58/114 reads (51%) | catalogued as rs771976753; called by mutect2, varscan2
- CPSF1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs782090510, COSV62938935; called by muse, mutect2, varscan2
- CPXM2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749545644, COSV53857243; called by muse, mutect2, varscan2
- CREB3L4 | c.577_579del p.E193del | In Frame Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs769844271; called by pindel, varscan2
- CSGALNACT1 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.794); catalogued as rs200462016, COSV100174928; called by muse, mutect2, varscan2
- CSNK1A1L | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 92/141 reads (65%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs759647226, COSV65789767; called by muse, mutect2, varscan2
- CTCFL | c.1838A>G p.D613G | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99712620; called by muse, mutect2, varscan2
- CTPS1 | c.1727C>A p.P576H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101009330; called by muse, mutect2, varscan2
- CTSZ | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV99413560; called by muse, mutect2, varscan2
- CWH43 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.655); catalogued as COSV99893394; called by muse, mutect2, varscan2
- CYP3A4 | c.1137del p.D380Mfs*15 | Frame Shift Del (DEL) | VAF 32/143 reads (22%) | catalogued as rs1183533325; called by mutect2, pindel, varscan2
- DCHS1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.33); catalogued as rs200795531, COSV55031852; called by muse, mutect2, varscan2
- DEPDC5 | c.2272T>C p.Y758H (on ENST00000400246; = p.Y827H on NM_014662.5) | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV99835308; called by muse, mutect2, varscan2
- DHX9 | c.983G>A p.G328D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as COSV100841398; called by muse, mutect2, varscan2
- DIDO1 | c.4550C>T p.S1517L | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs778919517, COSV99825806; called by muse, mutect2, varscan2
- DISP2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99139976; called by muse, mutect2, varscan2
- DKK2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753265155, COSV53397089; called by muse, mutect2, varscan2
- DLGAP4 | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100211212; called by muse, mutect2, varscan2
- DLL1 | c.845dup p.L283Pfs*14 | Frame Shift Ins (INS) | VAF 22/51 reads (43%) | catalogued as rs760008381; called by mutect2, varscan2
- DLX3 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV101460551; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH11 | c.12824dup p.N4275Kfs*4 | Frame Shift Ins (INS) | VAF 32/88 reads (36%) | catalogued as rs751061873; called by mutect2, varscan2
- DNAH2 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.37); catalogued as rs201520989, COSV50013941; called by muse, mutect2, varscan2
- DNAH3 | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1178099723, COSV54531763; called by muse, mutect2, varscan2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH8 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs754133293, COSV100543679, COSV100545147; called by muse, mutect2, varscan2
- DNAH9 | c.8560G>A p.G2854S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs145531006, COSV52352064, COSV99305793; called by muse, mutect2, varscan2
- DNAI1 | c.1355_1357del p.F452del | In Frame Del (DEL) | VAF 42/170 reads (25%) | catalogued as rs759609265; called by pindel, varscan2
- DOC2A | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1346621524, COSV58750681; called by muse, mutect2, varscan2
- DSCAM | c.4645C>T p.R1549W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs779003144, COSV101260082; called by muse, mutect2, varscan2
- DSCAML1 | c.596G>A p.G199D (on ENST00000321322; = p.G139D on NM_020693.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100355937; called by muse, mutect2, varscan2
- DST | c.15853G>T p.E5285* (on ENST00000361203 / NM_001374722.1; = p.E2873* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV55009701; called by muse, mutect2, varscan2
- DYNC2LI1 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99571185; called by muse, mutect2, varscan2
- DYRK3 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 50/141 reads (35%) | catalogued as COSV65607907; called by muse, mutect2, varscan2
- DYRK3 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1279890962, COSV65607783; called by muse, mutect2, varscan2
- EEF2K | c.926_928del p.F309del | In Frame Del (DEL) | VAF 32/107 reads (30%) | catalogued as rs564173710; called by pindel, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- EFNB2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as rs777601389, COSV99808537; called by muse, varscan2
- EGFLAM | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs775099439, COSV100380332, COSV59297222; called by muse, mutect2, varscan2
- EGFR | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV99290867; called by muse, mutect2, varscan2
- EIF3A | c.2440_2442del p.E814del | In Frame Del (DEL) | VAF 80/424 reads (19%) | catalogued as rs770493523; called by pindel, varscan2
- ELOA2 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745354631, COSV99796569; called by muse, mutect2, varscan2
- EPS15L1 | c.1313T>A p.L438H | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50168739, COSV99933042; called by muse, mutect2, varscan2
- ERC2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369782814; called by muse, mutect2, varscan2
- ERCC6L2 | c.1750A>C p.M584L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV99998590; called by muse, mutect2, varscan2
- EVA1B | c.66C>T p.R22= | Splice Region (SNP) | VAF 34/117 reads (29%) | catalogued as COSV99584075; called by muse, mutect2, varscan2
- FAM110A | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99856720; called by muse, mutect2
- FAM131A | c.639C>A p.C213* (on ENST00000310585; = p.C244* on NM_144635.5) | Nonsense Mutation (SNP) | VAF 13/196 reads (7%) | catalogued as COSV55599984, COSV99658555; called by muse, mutect2
- FAM186B | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV99218952; called by muse, mutect2, varscan2
- FAM20A | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99873332; called by muse, mutect2, varscan2
- FAM219A | c.492del p.K165Sfs*3 (on ENST00000445726; = p.K148Sfs*3 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs760074479; called by mutect2, pindel, varscan2
- FAT4 | c.9670G>C p.D3224H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100628569; called by muse, mutect2, varscan2
- FBL | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs377432606; called by muse, mutect2, varscan2
- FBLN1 | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.15); catalogued as rs149912059; called by muse, mutect2, varscan2
- FBXO46 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs984787955, COSV58349569; called by muse, mutect2
- FGFR2 | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100336196; called by muse, mutect2, varscan2
- FIGN | c.210del p.K70Nfs*29 | Frame Shift Del (DEL) | VAF 23/185 reads (12%) | catalogued as rs749851531; called by mutect2, pindel, varscan2
- FTSJ3 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 43/95 reads (45%) | catalogued as rs1357453628, COSV100834920; called by muse, mutect2, varscan2
- FUT1 | c.785G>A p.S262N | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100038122; called by muse, mutect2, varscan2
- GABARAPL1 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.148); catalogued as COSV99845468; called by muse, mutect2
- GALNT14 | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs768286610, COSV100204648; called by muse, mutect2, varscan2
- GCK | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.372); catalogued as COSV100357183; called by muse, mutect2, varscan2
- GNAI1 | c.684T>G p.S228R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100650499; called by muse, mutect2, varscan2
- GNAS | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.164); catalogued as rs758829628, COSV99669998; called by muse, mutect2, varscan2
- GNB1L | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs149599532; called by muse, mutect2, varscan2
- GNPDA2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV99776915; called by muse, mutect2, varscan2
- GORAB | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV100883766; called by muse, mutect2, varscan2
- GPR155 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as rs146408702; called by muse, mutect2, varscan2
- GPR179 | c.3800C>T p.P1267L (on ENST00000621958; = p.P1266L on NM_001004334.4) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as rs1182886204; called by muse, mutect2, varscan2
- GRID2 | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.748); catalogued as COSV56259296, COSV99940748; called by muse, mutect2, varscan2
- GRIK5 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756032803, COSV53479514; called by muse, mutect2, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as COSV58051797; called by mutect2, varscan2
- GRIN2D | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54382048; called by muse, mutect2, varscan2
- GRIN3A | c.2117A>C p.K706T | Missense Mutation (SNP) | VAF 144/307 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100701490; called by muse, mutect2, varscan2
- GRK7 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 83/171 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs142109851; called by muse, mutect2, varscan2
- GRM3 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs541049570, COSV100862532; called by muse, mutect2, varscan2
- GSE1 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.614); catalogued as COSV99496519; called by muse, mutect2, varscan2
- GSG1L | c.736A>G p.I246V (on ENST00000447459 / NM_001109763.2; = p.I91V on NM_144675.2) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.403); catalogued as COSV101093702; called by muse, mutect2, varscan2
- GTF2IRD2 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs782082645, COSV100736418; called by muse, mutect2, varscan2
- GTF3C3 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV99826700; called by muse, mutect2, varscan2
- GYS2 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679748; called by muse, mutect2, varscan2
- GZF1 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100582518; called by muse, mutect2, varscan2
- H4C4 | c.294_295del p.Y99Wfs*? | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | catalogued as rs775510690; called by mutect2, pindel, varscan2
- HAS1 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.769); catalogued as rs775182179, COSV55786197; called by muse, mutect2, varscan2
- HCN3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs748591685, COSV100855662; called by muse, mutect2, varscan2
- HDAC5 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs370605385; called by muse, mutect2, varscan2
- HDLBP | c.3437G>A p.R1146H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as rs768699303, COSV60492615; called by muse, mutect2, varscan2
- HERC1 | c.6935_6937del p.G2312del | In Frame Del (DEL) | VAF 33/112 reads (29%) | catalogued as rs932955902; called by pindel, varscan2
- HJURP | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as COSV100982598; called by muse, mutect2, varscan2
- HLCS | c.1121G>A p.S374N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV100358187; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1054C>T p.R352* (on ENST00000354667 / NM_031243.3; = p.R340* on NM_002137.4) | Nonsense Mutation (SNP) | VAF 58/219 reads (26%) | catalogued as COSV100668250; called by muse, mutect2, varscan2
- HOXA5 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as COSV99762306; called by muse, mutect2, varscan2
- HPD | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as rs745739337, COSV100000098; called by muse, mutect2, varscan2
- HRNR | c.3133G>A p.G1045S | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as rs754771130, COSV100913304, COSV64253745; called by muse, mutect2, varscan2
- HTR2A | c.1289del p.K430Rfs*19 | Frame Shift Del (DEL) | VAF 87/175 reads (50%) | catalogued as rs1398128295; called by mutect2, pindel, varscan2
- HYDIN | c.11557C>T p.P3853S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.646); catalogued as COSV101125075; called by muse, mutect2, varscan2
- IGHMBP2 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99662072; called by muse, mutect2, varscan2
- IGHV3-16 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs377684608; called by muse, mutect2, varscan2
- IGHV3-74 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as rs1567888222; called by muse, mutect2
- IGSF21 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); catalogued as COSV99244789; called by muse, mutect2, varscan2
- IGSF3 | c.3106G>A p.V1036M (on ENST00000369486 / NM_001007237.3; = p.V1056M on NM_001542.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as rs778484193, COSV59591088; called by muse, mutect2, varscan2
- IHO1 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs372514148, COSV56511435; called by muse, mutect2, varscan2
- IKZF2 | c.262A>T p.S88C | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV100563528; called by muse, mutect2, varscan2
- IL17RA | c.1513A>G p.S505G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs761567739, COSV100083113; called by muse, mutect2
- IL4 | c.335G>T p.R112M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99185000; called by muse, mutect2, varscan2
- INKA2 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as rs376225653; called by muse, mutect2, varscan2
- IRF1 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 8/200 reads (4%) | catalogued as COSV99810506; called by muse, mutect2
- IRX1 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.216); catalogued as COSV100116509, COSV57357891; called by muse, varscan2
- ISOC2 | c.448C>T p.R150C (on ENST00000425675 / NM_001136201.2; = p.R166C on NM_024710.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776527680, COSV99321180; called by muse, mutect2, varscan2
- ITGA2B | c.1865A>G p.H622R | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.959); catalogued as COSV99288850; called by muse, mutect2, varscan2
- ITGA3 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99143629; called by muse, mutect2, varscan2
- ITGA6 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.855); catalogued as COSV99905496; called by muse, mutect2, varscan2
- ITGA7 | c.3483C>G p.I1161M (on ENST00000555728; = p.I1117M on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99145687; called by muse, mutect2, varscan2
- JRK | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs17846351, COSV101401095; called by muse, mutect2, varscan2
- KCNC2 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54372281; called by muse, mutect2, varscan2
- KCNE1 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100492504; called by mutect2, varscan2
- KCNH2 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs764666519, COSV51132535; called by muse, mutect2, varscan2
- KCNH7 | c.468A>T p.K156N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as rs777345773, COSV59809157; called by muse, mutect2, varscan2
- KCNK3 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57192575; called by muse, mutect2, varscan2
- KCNU1 | c.895G>T p.G299W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101299190; called by muse, mutect2
- KIRREL3 | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101585723, COSV101585931; called by muse, mutect2, varscan2
- KLHDC8A | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs371340781; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs756907493; called by mutect2, pindel, varscan2
- KMT2A | c.8717C>A p.P2906H | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV63287914; called by muse, mutect2, varscan2
- KNDC1 | c.3005C>T p.A1002V | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs767156676, COSV100464717; called by muse, mutect2, varscan2
- KNL1 | c.5438C>T p.T1813M (on ENST00000346991 / NM_170589.5; = p.T1787M on NM_144508.5) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs556149056, COSV61154015; called by muse, mutect2, varscan2
- KRT16 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV100052928; called by muse, mutect2, varscan2
- KRT6C | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99359969; called by muse, mutect2, varscan2
- KRT82 | c.1535A>C p.K512T | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV99233573; called by muse, mutect2, varscan2
- KRTAP19-3 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 94/334 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs529648956, COSV100477445; called by muse, mutect2, varscan2
- LASP1 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100530365; called by muse, mutect2, varscan2
- LCOR | c.3661G>A p.A1221T | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as rs369997809, COSV53714356; called by muse, mutect2, varscan2
- LIM2 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99702360; called by muse, mutect2, varscan2
- LINGO1 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs767527970, COSV100796379; called by muse, mutect2, varscan2
- LMLN | c.1817C>A p.P606H | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100218553; called by muse, mutect2, varscan2
- LPL | c.223A>G p.T75A | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV100255582; called by muse, mutect2, varscan2
- LRIG1 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs146697512; called by muse, mutect2, varscan2
- LRP1 | c.7963G>A p.V2655M | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs769966821, COSV99675758; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | catalogued as rs757410385; called by mutect2, varscan2
- LRRC10 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs372742540; called by muse, mutect2, varscan2
- LRRC7 | c.727C>G p.Q243E (on ENST00000651989 / NM_001370785.2; = p.Q210E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV50533421, COSV50652759, COSV99226771; called by muse, mutect2, varscan2
- LYST | c.2156T>C p.I719T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV101089330; called by muse, mutect2, varscan2
- MAGEA3 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as rs370292729, COSV100939048; called by muse, mutect2, varscan2
- MAN2B2 | c.2605G>A p.V869M | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs540480695, COSV53455582; called by muse, mutect2, varscan2
- MANEA | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as rs755535602, COSV62589946; called by muse, mutect2
- MAPKBP1 | c.4123G>A p.V1375I (on ENST00000456763 / NM_001128608.2; = p.V1369I on NM_014994.3) | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.036); catalogued as COSV99529393; called by muse, mutect2, varscan2
- MAST2 | c.4436G>A p.G1479D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV100788091; called by muse, mutect2, varscan2
- MBD1 | c.1666G>A p.A556T (on ENST00000269468 / NM_001323950.1; = p.A454T on NM_002384.2) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV99496292; called by muse, mutect2, varscan2
- MCF2L2 | c.1675+2T>C p.X559_splice | Splice Site (SNP) | VAF 31/88 reads (35%) | catalogued as COSV100192506; called by muse, mutect2, varscan2
- MEGF8 | c.5422G>A p.E1808K (on ENST00000251268 / NM_001271938.2; = p.E1741K on NM_001410.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as rs771890594, COSV99236151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs745891632; called by mutect2, varscan2
- MLYCD | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as rs142671250; called by muse, mutect2, varscan2
- MMP27 | c.881A>C p.E294A | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99498375, COSV99498429; called by muse, mutect2, varscan2
- MPHOSPH9 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100186787; called by muse, mutect2
- MROH2B | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs563729861, COSV101270671; called by muse, mutect2, varscan2
- MRPL46 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 51/139 reads (37%) | catalogued as rs768892557, COSV56899680; called by muse, mutect2, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 41/171 reads (24%) | catalogued as rs34028511; called by mutect2, pindel, varscan2
- MSANTD3 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58495250; called by muse, mutect2, varscan2
- MUC17 | c.12035G>A p.S4012N | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1431799710, COSV60280286; called by muse, mutect2, varscan2
- MYBPC3 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.58); catalogued as rs776834755, CM115900, COSV99908907; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYD88 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as rs764428425, COSV100086096; called by muse, mutect2, varscan2
- MYO1A | c.1655C>A p.P552H | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270923; called by muse, mutect2, varscan2
- MYO5C | c.4213C>T p.R1405C | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs570238090, COSV55903612; called by muse, mutect2, varscan2
- MYT1L | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV101220731; called by muse, mutect2, varscan2
- NAV2 | c.5715G>A p.M1905I (on ENST00000396087 / NM_001244963.2; = p.M1846I on NM_145117.5) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs774644245, COSV100216848; called by muse, mutect2, varscan2
- NBN | c.2185G>A p.V729I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.57); catalogued as COSV55376794, COSV99619428; called by muse, mutect2
- NCDN | c.1347del p.T450Pfs*22 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as COSV61934732; called by mutect2, pindel, varscan2
- NCOA2 | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs747465366, COSV99144833; called by muse, mutect2, varscan2
- NEU2 | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV99290551; called by muse, mutect2, varscan2
- NFKB2 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs1383601570, COSV99192657; called by muse, mutect2, varscan2
- NID2 | c.3682C>G p.L1228V | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1408591273, COSV99356517; called by muse, mutect2, varscan2
- NIN | c.2276C>G p.T759S | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.295); catalogued as COSV99813478; called by muse, mutect2, varscan2
- NOA1 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.018); catalogued as COSV99950517; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | catalogued as rs759637346; called by mutect2, varscan2
- NPAS2 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as rs148668573, COSV100176179; called by muse, mutect2, varscan2
- NPBWR1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs1164727354, COSV100488206; called by muse, mutect2
- NR1D2 | c.1442A>T p.D481V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV100437436; called by muse, mutect2, varscan2
- NRXN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV68006658; called by muse, mutect2
- NUAK1 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99776982; called by muse, mutect2, varscan2
- NUP160 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 17/97 reads (18%) | catalogued as rs755224636, COSV65853707; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs760869296; called by mutect2, varscan2
- NYNRIN | c.3734G>A p.R1245Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs368016452, COSV66844100; called by muse, mutect2, varscan2
- OCLN | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs1275859439, COSV100783817; called by muse, mutect2, varscan2
- OFD1 | c.2737G>C p.E913Q | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100366204; called by muse, mutect2, varscan2
- OGFOD2 | c.413G>A p.R138H (on ENST00000228922 / NM_001304833.1; = p.R78H on NM_024623.3) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs760872313, COSV57441911; called by muse, mutect2, varscan2
- OIT3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 92/327 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs763495337, COSV100467959; called by muse, mutect2, varscan2
- OLFML2A | c.354+2T>C p.X118_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | catalogued as rs771037589, COSV100053707; called by muse, mutect2, varscan2
- OOEP | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64859125; called by muse, mutect2, varscan2
- OR12D2 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs757872667, COSV65827742; called by muse, mutect2, varscan2
- OR2AG2 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as rs771431828, COSV58455329; called by muse, mutect2, varscan2
- OR2T35 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs146528192, COSV100442276; called by muse, mutect2, varscan2
- OR4C3 | c.179dup p.L61Pfs*8 | Frame Shift Ins (INS) | VAF 16/88 reads (18%) | catalogued as rs777276396; called by mutect2, pindel, varscan2
- OR56B1 | c.739C>A p.L247M | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100402621; called by muse, mutect2, varscan2
- OR8D4 | c.14del p.N5Tfs*5 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as COSV58431151; called by mutect2, pindel, varscan2
- OTUD7A | c.1822G>A p.A608T (on ENST00000307050 / NM_001382637.1; = p.A601T on NM_130901.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV100192473; called by muse, mutect2
- OTX1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1262431691, COSV99246317; called by muse, mutect2, varscan2
- P2RY13 | c.468dup p.P157Tfs*55 | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | catalogued as rs1560033985; called by mutect2, varscan2
- PADI2 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs746982569, COSV100970932; called by muse, mutect2, varscan2
- PADI2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as rs148878349; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PBRM1 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV56276994; called by muse, mutect2, varscan2
- PCDH10 | c.679dup p.Q227Pfs*19 | Frame Shift Ins (INS) | VAF 20/58 reads (34%) | catalogued as rs762465989; called by mutect2, varscan2
- PCDHA4 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV100793423; called by muse, mutect2, varscan2
- PCDHB13 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99506986, COSV99507238; called by muse, mutect2, varscan2
- PCDHB9 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.856); catalogued as rs782097852, COSV53377701; called by muse, mutect2, varscan2
- PCDHGB1 | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773877160, COSV99537910; called by muse, mutect2, varscan2
- PCNX2 | c.2060G>A p.S687N | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV99267497; called by muse, mutect2
- PDCD11 | c.4414G>T p.E1472* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV100874327; called by muse, mutect2, varscan2
- PDE6A | c.2131G>A p.V711I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.131); catalogued as rs764962408, COSV54925482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKL | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs780393245, COSV100826973; called by muse, varscan2
- PHF21A | c.1955dup p.A653Cfs*22 (on ENST00000418153 / NM_001101802.3; = p.A607Cfs*22 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs761575760; called by mutect2, varscan2
- PI4KB | c.1132G>A p.V378M (on ENST00000368873 / NM_001369623.1; = p.V390M on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs764847655, COSV99649727; called by muse, mutect2, varscan2
- PKDCC | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as rs1482020645, COSV99684837; called by muse, mutect2, varscan2
- PLCB2 | c.2505G>T p.E835D | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99542061; called by muse, mutect2
- PLCB3 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201041817, COSV54191224, COSV99657393; called by muse, mutect2, varscan2
- PLCL1 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559099836, COSV70821454, COSV70821834; called by muse, mutect2, varscan2
- PLD6 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs375940521; called by muse, varscan2
- PM20D2 | c.770del p.N257Mfs*4 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | catalogued as rs1214792276; called by mutect2, pindel, varscan2
- POGLUT1 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs748170466, COSV55156785; called by muse, mutect2, varscan2
- POU2F2 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100657352; called by muse, mutect2, varscan2
- PPP2R3B | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs760244257, COSV66813342; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 24/84 reads (29%) | catalogued as rs778683789; called by mutect2, varscan2
- PRMT3 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 27/110 reads (25%) | catalogued as rs376995112; called by muse, mutect2, varscan2
- PRSS22 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV99361841; called by muse, mutect2, varscan2
- PTH2R | c.855G>A p.G285= | Splice Region (SNP) | VAF 29/141 reads (21%) | catalogued as rs375705130; called by muse, mutect2, varscan2
- PTPN14 | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100872553; called by muse, mutect2, varscan2
- PXDNL | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV62476741; called by muse, mutect2, varscan2
- PXN | c.144del p.V49Sfs*18 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs758654594; called by mutect2, pindel, varscan2
- QRFPR | c.428G>A p.R143K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100543715; called by muse, mutect2, varscan2
- RASGRF2 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs749203214, COSV54124613; called by muse, mutect2, varscan2
- RELA | c.1494G>T p.E498D | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.899); catalogued as COSV100425825; called by muse, mutect2, varscan2
- RELB | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.602); catalogued as COSV99672891; called by muse, mutect2, varscan2
- REPIN1 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766431446, COSV101262614; called by muse, mutect2, varscan2
- RET | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1057521089, CM119573, COSV60701849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RETREG2 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as rs534065470, COSV99811541, COSV99811662; called by muse, mutect2, varscan2
- RFK | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100946894; called by muse, mutect2
- RGL1 | c.2290A>C p.S764R (on ENST00000360851 / NM_001297672.2; = p.S799R on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100486708; called by muse, mutect2, varscan2
- RHBDF2 | c.1725+2T>C p.X575_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | catalogued as COSV99166214; called by muse, mutect2, varscan2
- RHBDF2 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs377108423, COSV100489384; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 57/211 reads (27%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RIPK4 | c.1984C>T p.R662C (on ENST00000352483; = p.R614C on NM_020639.3) | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1255352381, COSV100204926; called by muse, mutect2, varscan2
- RLF | c.1436G>A p.C479Y | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65653308; called by muse, mutect2, varscan2
- RNASEH2B | c.509del p.K170Rfs*9 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | catalogued as rs1085307091, COSV60747894; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- RNF145 | c.767G>A p.R256H (on ENST00000424310 / NM_001199383.2; = p.R284H on NM_144726.2) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as COSV99193509; called by muse, mutect2, varscan2
- RNF217 | c.1544C>T p.A515V (on ENST00000521654 / NM_001286398.2; = p.A223V on NM_152553.5) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.811); catalogued as rs772079217, COSV99255043; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs752898741; called by mutect2, varscan2
- RORA | c.1467G>T p.M489I (on ENST00000335670 / NM_134261.3; = p.M514I on NM_002943.3) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99832622; called by muse, mutect2, varscan2
- RP9 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs762116266, COSV99777966; called by mutect2, varscan2
- RPE65 | c.886del p.R296Gfs*29 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | catalogued as rs746127684; called by mutect2, pindel, varscan2
- RPL23A | c.219C>A p.H73Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV99411744; called by muse, mutect2, varscan2
- RUVBL2 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762109573, COSV99669002; called by muse, mutect2
- RYR2 | c.1397del p.P466Qfs*5 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as COSV100771204; called by mutect2, pindel, varscan2
- RYR2 | c.3841C>T p.P1281S | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100770035, COSV63702764; called by muse, mutect2, varscan2
- SALL4 | c.3019G>A p.V1007I | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as rs1276442318, COSV99409496; called by muse, mutect2, varscan2
- SAMD9 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV101180250, COSV66077098; called by muse, mutect2, varscan2
- SBF2 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs900191960, COSV56312339; called by muse, mutect2
- SCRIB | c.4537G>A p.A1513T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100253242; called by muse, mutect2, varscan2
- SCRIB | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1403510676, COSV100253249; called by muse, mutect2
- SCYL1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.636); catalogued as rs1227740483, COSV99534067; called by muse, mutect2, varscan2
- SDK2 | c.1663C>T p.H555Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.317); catalogued as rs200915505, COSV66185518; called by muse, mutect2, varscan2
- SEC62 | c.429del p.D144Mfs*58 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs751191303; called by mutect2, varscan2
- SEMA3E | c.2315C>T p.T772M | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs766002060, COSV57113635, COSV99080328; called by muse, mutect2, varscan2
- SEMA5B | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs761710015, COSV99531749; called by muse, varscan2
- SIMC1 | c.2152C>T p.R718C (on ENST00000443967 / NM_001308196.1; = p.R303C on NM_198567.5) | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564067290, COSV100231112; called by muse, mutect2, varscan2
- SLC18A2 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as rs775978426, COSV100041637; called by muse, mutect2, varscan2
- SLC1A4 | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV99308950; called by muse, mutect2, varscan2
- SLC25A20 | c.401T>A p.I134N | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100033729; called by muse, mutect2, varscan2
- SLC25A31 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1270543795, COSV55420168; called by muse, mutect2, varscan2
- SLC27A6 | c.185G>T p.S62I | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99322671; called by muse, mutect2, varscan2
- SLC4A10 | c.2911G>T p.D971Y (on ENST00000446997 / NM_001354461.2; = p.D941Y on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763970; called by muse, mutect2, varscan2
- SLC4A4 | c.859G>A p.V287M (on ENST00000264485 / NM_001098484.3; = p.V243M on NM_003759.4) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs201871554, COSV52627879; called by muse, mutect2, varscan2
- SLC8A3 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as COSV100776182; called by muse, mutect2, varscan2
- SLC9B1 | c.138A>G p.I46M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56467318; called by muse, mutect2, varscan2
- SLCO3A1 | c.1945A>T p.R649W | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100575379; called by muse, mutect2, varscan2
- SLCO5A1 | c.2495C>A p.S832Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV99479988; called by muse, mutect2, varscan2
- SNF8 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.658); catalogued as COSV99287789; called by muse, mutect2, varscan2
- SNRNP200 | c.3355G>A p.D1119N | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs756195450, COSV60493678; called by muse, mutect2, varscan2
- SORBS3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs375539049; called by muse, mutect2, varscan2
- SP100 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99893192; called by muse, mutect2, varscan2
- SP100 | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as rs534239970, COSV60849846; called by muse, mutect2, varscan2
- SP2 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as rs774644043, COSV100947186; called by muse, mutect2, varscan2
- SPATA2 | c.238T>A p.S80T | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.421); catalogued as COSV99192811; called by muse, mutect2, varscan2
- SPATA31D1 | c.2830C>A p.L944I | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.381); catalogued as COSV100782766; called by muse, mutect2, varscan2
- SPATA6 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs148746931; called by muse, mutect2, varscan2
- SPHK2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1218847539, COSV55334766; called by muse, varscan2
- SPTB | c.2912C>T p.T971M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs138556050; called by muse, mutect2, varscan2
- SPTBN5 | c.4097G>A p.R1366H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs747726960, COSV100311373; called by muse, mutect2, varscan2
- SRPRA | c.509A>G p.K170R | Missense Mutation (SNP) | VAF 107/326 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as rs753758817, COSV55007115; called by mutect2, varscan2
- SRRM1 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs747316883, COSV100104066; called by muse, mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs753297385; called by mutect2, varscan2
- SSBP2 | c.152del p.N51Tfs*54 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs1057518330; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SSUH2 | c.476A>T p.H159L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.083); catalogued as COSV100435809; called by muse, mutect2, varscan2
- STON1 | c.2148del p.K717Sfs*17 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | catalogued as rs1226688483, COSV59128600, COSV59129288; called by mutect2, pindel, varscan2
- STX16 | c.605T>C p.V202A (on ENST00000371141 / NM_001001433.3; = p.V181A on NM_003763.6) | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as COSV100397409; called by muse, mutect2
- STYXL1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs782472686, COSV99951414; called by muse, mutect2, varscan2
- SUCO | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99742767; called by muse, mutect2, varscan2
- SUGP2 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs759643188, COSV58255303; called by muse, mutect2, varscan2
- SULT1B1 | c.92T>G p.I31S | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100150254, COSV100150503; called by muse, mutect2, varscan2
- SUSD2 | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs375763524; called by muse, mutect2, varscan2
- SV2A | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs782452680, COSV100975151; called by muse, mutect2, varscan2
- SYNCRIP | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.964); catalogued as COSV62286853, COSV62287000; called by muse, mutect2, varscan2
- SYNE2 | c.8891G>A p.R2964H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs769752828, COSV59948760; called by muse, mutect2, varscan2
- TBC1D28 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.193); catalogued as rs202167244, COSV100561000; called by muse, mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 38/106 reads (36%) | catalogued as rs753315680; called by mutect2, varscan2
- TIMP3 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs779515006, COSV56667599; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | catalogued as rs760930120; called by mutect2, varscan2
- TMEM101 | c.136C>A p.R46= | Splice Region (SNP) | VAF 9/242 reads (4%) | catalogued as COSV99243801; called by muse, mutect2
- TMEM127 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99302609; called by muse, mutect2
- TMEM214 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1026071177, COSV99476269; called by muse, mutect2, varscan2
- TMIGD3 | c.610C>T p.R204C (on ENST00000369717 / NM_001081976.2; = p.R285C on NM_020683.7) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs148883954, COSV100778408; called by muse, mutect2, varscan2
- TNRC18 | c.7403G>A p.G2468D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV100078826; called by muse, mutect2, varscan2
- TP53I13 | c.772del p.A258Rfs*60 | Frame Shift Del (DEL) | VAF 28/126 reads (22%) | catalogued as COSV99838092; called by mutect2, pindel, varscan2
- TP73 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs574845163, COSV60705726; called by muse, varscan2
- TRANK1 | c.4261del p.D1421Tfs*7 | Frame Shift Del (DEL) | VAF 51/127 reads (40%) | catalogued as rs866661054; called by mutect2, pindel, varscan2
- TRIM2 | c.1120G>A p.G374R (on ENST00000437508; = p.G401R on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223115826, COSV100107466, COSV100107917; called by muse, mutect2, varscan2
- TRIM23 | c.1142T>C p.I381T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV99139988; called by muse, mutect2, varscan2
- TRIM3 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as rs778812981, COSV61985514; called by muse, mutect2, varscan2
- TRIM35 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs777215107, COSV59523486; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 44/90 reads (49%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIM9 | c.1529A>G p.N510S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV100031375; called by muse, mutect2, varscan2
- TRIT1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as rs149680997; called by muse, mutect2, varscan2
- TRMT10C | c.393del p.K131Nfs*3 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs760928888; called by mutect2, varscan2
- TRO | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as rs999268113, COSV51502353; called by muse, mutect2, varscan2
- TSPAN9 | c.380A>G p.H127R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1201909469, COSV99170867; called by muse, mutect2
- TSTD2 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 115/229 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs141485506; called by muse, mutect2, varscan2
- TTLL12 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99333426; called by muse, mutect2, varscan2
- TTN | c.89904C>T p.Y29968= (on ENST00000591111; = p.Y22544= on NM_003319.4) | Splice Region (SNP) | VAF 9/38 reads (24%) | catalogued as rs771635198, COSV60177342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.4801T>C p.Y1601H (on ENST00000591111; = p.Y1555H on NM_003319.4) | Missense Mutation (SNP) | VAF 36/145 reads (25%) | PolyPhen benign (0.015); catalogued as COSV100611841; called by muse, mutect2, varscan2
- TUBGCP5 | c.2136del p.D713Ifs*5 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as rs1432092958; called by mutect2, pindel, varscan2
- TUT1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV99545291; called by muse, mutect2, varscan2
- TUT4 | c.4619T>G p.V1540G | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV99932314; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as rs760251146; called by mutect2, varscan2
- UBQLN1 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99973302; called by muse, mutect2, varscan2
- UBR4 | c.3989G>A p.S1330N | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs1384512945, COSV100920759; called by muse, mutect2, varscan2
- UNC79 | c.3623T>C p.L1208S (on ENST00000393151 / NM_001346218.2; = p.L1031S on NM_020818.5) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV99827758; called by muse, mutect2, varscan2
- UNC93B1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs190159924, COSV57098321, COSV57100430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP39 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60383923; called by muse, mutect2, varscan2
- VARS2 | c.1816C>A p.L606I | Missense Mutation (SNP) | VAF 87/130 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1367571573, COSV100422873; called by muse, mutect2, varscan2
- VDAC3 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs751469875, COSV99195118; called by muse, mutect2, varscan2
- VPS16 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs774866901, COSV100988483; called by muse, mutect2, varscan2
- VPS33A | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV99931363; called by muse, mutect2, varscan2
- VPS35L | c.2583_2585del p.N861del | In Frame Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs767894566; called by pindel, varscan2
- VPS52 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs775407704, COSV71403456; called by muse, mutect2, varscan2
- VSIG1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs755042895, COSV54257901; called by muse, mutect2
- VWA3B | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101346031; called by muse, mutect2, varscan2
- VWA7 | c.522_523del p.Y174* | Nonsense Mutation (DEL) | VAF 12/49 reads (24%) | catalogued as rs766406434; called by mutect2, pindel, varscan2
- WDTC1 | c.868dup p.E290Gfs*7 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs747972901; called by mutect2, varscan2
- WNK1 | c.4726A>G p.I1576V (on ENST00000315939 / NM_018979.4; = p.I1329V on NM_014823.3) | Missense Mutation (SNP) | VAF 141/466 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs979662195, COSV100267316; called by muse, mutect2, varscan2
- WNK2 | c.6481G>A p.D2161N (on ENST00000297954 / NM_001282394.1; = p.D2124N on NM_006648.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1371734874, COSV52935878; called by muse, mutect2, varscan2
- WRAP53 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1013244580, COSV56834572; called by muse, mutect2
- XYLT2 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs369771174; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 21/99 reads (21%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZAP70 | c.1772A>C p.Q591P | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.335); catalogued as COSV99385494; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZFHX4 | c.4894G>T p.V1632L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99262543; called by muse, mutect2, varscan2
- ZFP69 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs41303439, COSV101018228; called by muse, mutect2, varscan2
- ZGRF1 | c.1825_1826del p.L609Afs*6 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as rs1249068282; called by pindel, varscan2
- ZNF112 | c.2288G>A p.R763H (on ENST00000337401 / NM_001083335.2; = p.R757H on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as rs764107629, COSV100495748; called by muse, mutect2, varscan2
- ZNF185 | c.1534A>G p.S512G | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as COSV100248382; called by muse, mutect2, varscan2
- ZNF19 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as COSV99867315; called by muse, mutect2, varscan2
- ZNF197 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100482084; called by muse, mutect2, varscan2
- ZNF296 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs756653209, COSV99673813; called by muse, mutect2, varscan2
- ZNF350 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99702523; called by muse, mutect2, varscan2
- ZNF420 | c.1903A>T p.R635* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100421345; called by muse, mutect2, varscan2
- ZNF429 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs771900629, COSV100641892, COSV61917286; called by muse, mutect2, varscan2
- ZNF446 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1221499003, COSV99543263; called by muse, mutect2, varscan2
- ZNF462 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.557); catalogued as rs775687483, COSV52943899, COSV99471902; called by muse, mutect2, varscan2
- ZNF462 | c.5171C>T p.A1724V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1396814594, COSV52947585; called by muse, mutect2, varscan2
- ZNF467 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100117932; called by muse, mutect2, varscan2
- ZNF548 | c.722T>C p.M241T | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100278129; called by muse, mutect2, varscan2
- ZNF576 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs769768399, COSV100338144; called by muse, mutect2, varscan2
- ZNF624 | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1212421435, COSV100257246; called by muse, mutect2, varscan2
- ZNF678 | c.495G>A p.W165* (on ENST00000343776 / NM_001367910.1; = p.W220* on NM_178549.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/149 reads (26%) | catalogued as rs775141189, COSV100652758, COSV59383625; called by muse, mutect2, varscan2
- ZNRF3 | c.2348A>C p.E783A (on ENST00000544604 / NM_001206998.2; = p.E683A on NM_032173.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as COSV100238442; called by muse, mutect2
- ZSCAN29 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99539066; called by muse, mutect2
- ABCA1 | c.4449del p.L1484Cfs*17 | Frame Shift Del (DEL) | VAF 45/129 reads (35%) | called by mutect2, pindel, varscan2
- ABCD1 | c.1708_1732del p.G570Pfs*58 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- ADGRG2 | c.2522del p.L841Yfs*4 (on ENST00000379869 / NM_001079858.3; = p.L838Yfs*4 on NM_005756.4) | Frame Shift Del (DEL) | VAF 86/160 reads (54%) | called by mutect2, pindel, varscan2
- ARHGAP28 | c.488del p.K163Rfs*107 (on ENST00000383472 / NM_001366230.1; = p.K4Rfs*107 on NM_001010000.3) | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- ARID1A | c.3861_3862del p.R1287Sfs*10 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by pindel, varscan2
- BCORL1 | c.2227del p.R743Afs*40 | Frame Shift Del (DEL) | VAF 26/55 reads (47%) | called by mutect2, pindel, varscan2
- BMPR2 | c.2238dup p.K747Qfs*11 | Frame Shift Ins (INS) | VAF 31/106 reads (29%) | called by mutect2, pindel, varscan2
- CENPK | c.232del p.T78Hfs*7 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- CFAP74 | c.1871T>A p.L624H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- CHD1 | c.1081del p.R361Dfs*3 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel
- CHD9 | c.7621dup p.R2541Kfs*9 (on ENST00000398510 / NM_001382353.1; = p.R2525Kfs*9 on NM_025134.7) | Frame Shift Ins (INS) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- CSMD1 | c.2438dup p.L813Ffs*40 (on ENST00000520002; = p.L812Ffs*40 on NM_033225.6) | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- DCSTAMP | c.429dup p.Y144Ifs*3 | Frame Shift Ins (INS) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- DDR1 | c.1803del p.R602Efs*51 (on ENST00000324771; = p.R565Efs*51 on NM_001954.4) | Frame Shift Del (DEL) | VAF 70/134 reads (52%) | called by mutect2, pindel, varscan2
- DENND4A | c.5235dup p.Y1746Ifs*11 | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- EFCAB7 | c.1138del p.I380* | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | called by mutect2, varscan2
- EPG5 | c.5704del p.Y1902Ifs*26 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | called by mutect2, varscan2
- EPRS1 | c.2177del p.N726Mfs*15 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- FAAH | c.694del p.L232Wfs*3 | Frame Shift Del (DEL) | VAF 44/183 reads (24%) | called by mutect2, pindel, varscan2
- FAM110A | c.618del p.F206Lfs*49 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- FAM90A1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by mutect2, varscan2
- FBXO31 | c.966del p.H322Qfs*27 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | called by mutect2, pindel, varscan2
- GLS | c.1085del p.L362* | Frame Shift Del (DEL) | VAF 32/100 reads (32%) | called by mutect2, pindel, varscan2
- IFITM1 | c.45del p.S16Afs*9 | Frame Shift Del (DEL) | VAF 29/137 reads (21%) | called by mutect2, pindel, varscan2
- IGF2R | c.690del p.G231Afs*7 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- JAK1 | c.425del p.K142Rfs*26 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, varscan2
- KCNAB3 | c.1079_1080del p.S360Cfs*131 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by pindel, varscan2
- KMT2B | c.3302del p.P1101Lfs*81 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- KNTC1 | c.1661del p.L554Yfs*3 | Frame Shift Del (DEL) | VAF 39/200 reads (20%) | called by mutect2, pindel, varscan2
- LGMN | c.886dup p.L296Pfs*8 | Frame Shift Ins (INS) | VAF 35/106 reads (33%) | called by mutect2, pindel, varscan2
- LRP12 | c.2543del p.N848Tfs*39 | Frame Shift Del (DEL) | VAF 28/88 reads (32%) | called by mutect2, pindel, varscan2
- MFSD14A | c.648_687del p.K216Nfs*9 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel
- MPHOSPH9 | c.2657del p.K886Sfs*11 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | called by mutect2, pindel, varscan2
- MYL10 | c.611del p.P204Qfs*42 | Frame Shift Del (DEL) | VAF 53/166 reads (32%) | called by mutect2, pindel, varscan2
- MYOD1 | c.650del p.P217Rfs*33 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel
- NCOR2 | c.2023_2025del p.K675del | In Frame Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- NOL6 | c.1558del p.A520Lfs*3 | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | called by mutect2, pindel, varscan2
- OSBPL11 | c.1341dup p.P448Tfs*27 | Frame Shift Ins (INS) | VAF 35/133 reads (26%) | called by mutect2, pindel, varscan2
- P2RX6 | c.605del p.N202Tfs*63 | Frame Shift Del (DEL) | VAF 39/136 reads (29%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 43/164 reads (26%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.908G>A p.C303Y | Missense Mutation (SNP) | VAF 165/568 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PTPRB | c.742del p.V248Wfs*13 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- RHBDF1 | c.1941del p.E648Rfs*30 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel
- RMI1 | c.615del p.V206Yfs*5 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | called by mutect2, pindel, varscan2
- SIGLEC10 | c.804del p.G269Afs*18 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- SNTG1 | c.1484del p.L495* | Frame Shift Del (DEL) | VAF 34/134 reads (25%) | called by mutect2, pindel, varscan2
- SOS1 | c.3090del p.K1030Nfs*6 | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | called by mutect2, pindel, varscan2
- SP100 | c.2282del p.K761Rfs*40 | Frame Shift Del (DEL) | VAF 32/90 reads (36%) | called by mutect2, varscan2
- SPHK2 | c.205del p.T70Hfs*138 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by pindel, varscan2
- SRGAP1 | c.168del p.A57Lfs*11 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | called by mutect2, pindel, varscan2
- SYNRG | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TG | c.8052del p.W2685Gfs*26 | Frame Shift Del (DEL) | VAF 27/130 reads (21%) | called by mutect2, pindel, varscan2
- TRIM33 | c.2132del p.P711Hfs*7 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- WNK2 | c.2594del p.P865Lfs*25 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, varscan2
- XIRP2 | c.1010del p.N337Tfs*2 (on ENST00000628543; = p.N512Tfs*2 on NM_152381.6) | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- YBX2 | c.457_459del p.K153del | In Frame Del (DEL) | VAF 43/148 reads (29%) | called by mutect2, pindel, varscan2
- ZBTB38 | c.2800del p.M934* | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- ZNF470 | c.631del p.T211Hfs*5 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- ZNF827 | c.3070del p.C1024Afs*33 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- AC068580.4 | c.969C>T p.G323= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs774332555, COSV99362376; called by muse, mutect2
- ACVR1 | c.258C>T p.S86= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs1304523905, COSV99717792; called by muse, mutect2, varscan2
- ADAMTS14 | c.2496G>A p.L832= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100941570; called by muse, mutect2, varscan2
- ADCY2 | c.1515G>A p.K505= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100602842; called by muse, mutect2, varscan2
- AIM2 | c.798T>G p.G266= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV100931071; called by muse, mutect2, varscan2
- AK7 | c.459G>A p.S153= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1386346088, COSV50870753, COSV50871036; called by muse, mutect2, varscan2
- ALKBH4 | c.165C>T p.A55= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as rs149560901; called by muse, mutect2, varscan2
- ANKRD28 | c.1617A>C p.T539= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV101080635; called by muse, mutect2, varscan2
- ARAP1 | c.1911G>A p.R637= (on ENST00000393609 / NM_001040118.2; = p.R392= on NM_015242.4) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100501897; called by muse, mutect2, varscan2
- AREL1 | c.741C>T p.L247= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100707606; called by muse, mutect2, varscan2
- ARFGEF3 | c.6462C>T p.T2154= | Silent (SNP) | VAF 53/109 reads (49%) | catalogued as rs745966364, COSV99293431; called by muse, mutect2, varscan2
- ARHGEF4 | c.1323G>A p.T441= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs1483318405, COSV58120480, COSV58127588; called by muse, mutect2, varscan2
- ARID1A | c.5871C>T p.D1957= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs761246391, COSV100251634; called by muse, mutect2, varscan2
- ATAD3A | c.1086G>A p.A362= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs982712511, COSV100186326; called by muse, mutect2, varscan2
- B3GAT1 | c.477C>T p.R159= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1247871633, COSV56998007; called by muse, mutect2, varscan2
- BCAN | c.1905C>T p.S635= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs761210707, COSV100228089; called by muse, mutect2, varscan2
- BCOR | c.876C>T p.G292= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as rs770716410, COSV60707904; called by muse, varscan2
- C12orf66 | c.657G>A p.A219= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs185163970, COSV61322261; called by muse, mutect2, varscan2
- C17orf97 | c.717C>T p.P239= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs1320174636, COSV100789338; called by muse, mutect2, varscan2
- CAPZA2 | c.369A>G p.S123= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as COSV100753909; called by muse, mutect2, varscan2
- CCDC122 | c.39T>C p.P13= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99865963; called by muse, mutect2, varscan2
- CCDC6 | c.1404G>A p.A468= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs144036104; called by muse, mutect2, varscan2
- CD96 | c.1248A>G p.S416= (on ENST00000283285 / NM_198196.3; = p.S400= on NM_005816.5) | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV99342869; called by muse, mutect2, varscan2
- CDAN1 | c.3472C>T p.L1158= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV99313816; called by muse, mutect2, varscan2
- CDC45 | c.625C>T p.L209= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV99596664; called by muse, mutect2, varscan2
- CDCA2 | c.1665G>A p.K555= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs776457934, COSV100398867; called by muse, mutect2, varscan2
- CDH10 | c.993T>C p.T331= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as COSV100051372; called by muse, mutect2, varscan2
- CDK20 | c.552C>T p.G184= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs754174793, COSV57481783; called by muse, mutect2
- CDKN2A | c.402G>A p.A134= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs878853649, COSV100446396; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CNOT4 | c.117A>T p.R39= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100211551; called by muse, mutect2, varscan2
- COL10A1 | c.1272G>A p.V424= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs749839210, COSV99684234; called by muse, mutect2, varscan2
- CPD | c.3528G>A p.P1176= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs758793987, COSV99852835; called by muse, mutect2, varscan2
- CYP19A1 | c.1458C>T p.N486= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as rs1380261840, COSV53061425, COSV99547682; called by muse, mutect2, varscan2
- DCST2 | c.384G>A p.E128= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1425885604, COSV99791906; called by muse, mutect2
- DUSP2 | c.906G>A p.G302= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99997070; called by muse, mutect2, varscan2
- EIF5B | c.393G>A p.V131= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV99177239; called by muse, mutect2, varscan2
- ENOX1 | c.123C>T p.S41= | Silent (SNP) | VAF 43/70 reads (61%) | catalogued as rs372756168, COSV54896881; called by muse, mutect2, varscan2
- EP300 | c.6090A>G p.Q2030= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs749621134, COSV99608484; called by muse, mutect2, varscan2
- EPDR1 | c.468A>G p.S156= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99554405; called by muse, mutect2, varscan2
- EPHA2 | c.1485C>T p.D495= | Silent (SNP) | VAF 70/294 reads (24%) | catalogued as rs768864167, COSV100626104; called by muse, mutect2, varscan2
- FAM170A | c.454T>C p.L152= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100088985; called by muse, mutect2, varscan2
- FBN3 | c.5601C>A p.S1867= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV99560881, COSV99562066; called by muse, mutect2, varscan2
- FBXL7 | c.1428C>T p.R476= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV61655350; called by muse, mutect2, varscan2
- FBXW10 | c.1071T>C p.D357= | Silent (SNP) | VAF 44/202 reads (22%) | catalogued as COSV100111431; called by muse, mutect2, varscan2
- FGF18 | c.441C>T p.S147= | Silent (SNP) | VAF 45/156 reads (29%) | catalogued as rs148727482; called by muse, mutect2, varscan2
- G6PC | c.324C>A p.T108= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as COSV99520824; called by muse, mutect2, varscan2
- GADL1 | c.708T>A p.V236= | Silent (SNP) | VAF 8/177 reads (5%) | catalogued as COSV99244376; called by muse, mutect2
- GCNA | c.1110T>C p.A370= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV101032520; called by muse, mutect2, varscan2
- GLIPR2 | c.168G>A p.P56= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs138525625; called by muse, mutect2, varscan2
- GOLGB1 | c.1920G>A p.A640= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs112783488, COSV61461418; called by muse, mutect2, varscan2
- GPBAR1 | c.561C>T p.R187= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs760312764, COSV99946330; called by muse, mutect2, varscan2
- GPR87 | c.300T>C p.H100= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV53462960; called by muse, mutect2, varscan2
- GTF3C2 | c.618G>A p.L206= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99272717; called by muse, mutect2, varscan2
- GTPBP4 | c.1218A>G p.G406= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100672643; called by muse, mutect2, varscan2
- HAS1 | c.1500C>T p.Y500= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99708392; called by muse, mutect2, varscan2
- HDLBP | c.1059G>A p.A353= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100190567, COSV60494654; called by muse, mutect2, varscan2
- HEATR5B | c.1218C>T p.G406= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs754241447, COSV51854087; called by muse, mutect2, varscan2
- HECW1 | c.2292C>T p.N764= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs1026932363, COSV101223494; called by muse, mutect2
- HMCN1 | c.12804C>T p.D4268= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs147822137, COSV54932998; called by muse, mutect2, varscan2
- HNRNPL | c.1002G>C p.G334= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs751667827, COSV99670288; called by muse, mutect2, varscan2
- HOXD12 | c.777C>T p.R259= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV66832562; called by muse, mutect2, varscan2
- HS3ST3A1 | c.717C>T p.I239= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as rs780055997, COSV52372470, COSV52378253; called by muse, mutect2, varscan2
- HTR3D | c.1086G>A p.A362= (on ENST00000382489 / NM_001163646.2; = p.A187= on NM_182537.3) | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs368199300; called by muse, mutect2, varscan2
- IBTK | c.600C>A p.T200= | Silent (SNP) | VAF 35/149 reads (23%) | catalogued as COSV100090702; called by muse, mutect2, varscan2
- IL20RB | c.312G>A p.T104= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs1310063356, COSV59049811; called by muse, mutect2, varscan2
- ITIH4 | c.2451G>A p.T817= | Silent (SNP) | VAF 78/204 reads (38%) | catalogued as rs755043796, COSV56573406; called by muse, mutect2, varscan2
- KAT7 | c.1644G>A p.T548= | Silent (SNP) | VAF 52/197 reads (26%) | catalogued as rs760641854, COSV99371754; called by muse, mutect2, varscan2
- KDM2B | c.480C>T p.Y160= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs782376095, COSV100997402, COSV65638436; called by muse, mutect2
- KIF3B | c.441C>A p.I147= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1283898845, COSV100996376; called by muse, mutect2, varscan2
- KMT2B | c.2289G>A p.P763= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs200332721, COSV52893008; called by muse, mutect2, varscan2
- KRT40 | c.717C>T p.G239= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs572577879, COSV66696634; called by muse, mutect2, varscan2
- KRT85 | c.69T>G p.A23= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV99225421; called by muse, mutect2, varscan2
- KRTAP10-9 | c.261G>A p.P87= | Silent (SNP) | VAF 86/256 reads (34%) | catalogued as rs782247632, COSV100553389; called by muse, mutect2, varscan2
- LDAH | c.625C>T p.L209= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV99425585; called by muse, mutect2, varscan2
- LEFTY2 | c.684C>T p.A228= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs751976627, COSV100832594; called by muse, mutect2, varscan2
- LRRC37A3 | c.1131G>A p.P377= | Silent (SNP) | VAF 120/366 reads (33%) | catalogued as rs532383533, COSV59762551; called by muse, mutect2, varscan2
- LSM14A | c.1110T>C p.F370= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1213686947, COSV101471691; called by muse, mutect2, varscan2
- LSS | c.837C>T p.N279= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs201096401, COSV100710906; called by muse, mutect2, varscan2
- MAP3K4 | c.2157G>A p.S719= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs536943325, COSV62338041; called by muse, mutect2, varscan2
- MCM3AP | c.3318C>T p.Y1106= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs558735247, COSV99386918; called by muse, mutect2, varscan2
- MDN1 | c.4248C>T p.C1416= | Silent (SNP) | VAF 39/139 reads (28%) | catalogued as rs764869819, COSV101021303; called by muse, mutect2, varscan2
- MGAM | c.3072C>T p.S1024= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as rs375312122, COSV72074934; called by muse, mutect2, varscan2
- MIIP | c.84G>A p.V28= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV52427837; called by muse, mutect2, varscan2
- MIOS | c.216T>C p.Y72= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as COSV100402762; called by muse, mutect2, varscan2
- MOGAT3 | c.75C>T p.G25= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs749717392, COSV56173768; called by muse, mutect2, varscan2
- MPP4 | c.651C>T p.I217= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV100206867, COSV59630504; called by muse, mutect2, varscan2
- MRPL33 | c.96C>A p.T32= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as COSV99941402; called by muse, mutect2, varscan2
- MST1R | c.3726A>G p.Q1242= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99618648; called by muse, mutect2
- MT1G | c.180C>T p.C60= (on ENST00000379811 / NM_001301267.2; = p.C59= on NM_005950.3) | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV100189991; called by muse, mutect2, varscan2
- MTG2 | c.1179G>A p.A393= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs767461500, COSV63694953; called by muse, mutect2, varscan2
- MTTP | c.2136T>C p.D712= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99645135; called by muse, mutect2, varscan2
- MUC16 | c.1714C>T p.L572= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV101199881; called by muse, mutect2, varscan2
- MYO16 | c.3891G>A p.P1297= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs151007439; called by muse, mutect2, varscan2
- MYORG | c.1899C>T p.I633= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs372037588; called by muse, mutect2
- NCOR1 | c.4623C>T p.V1541= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs369446328; called by muse, mutect2, varscan2
- NOTCH3 | c.5055C>T p.D1685= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs763442658, COSV99657164; called by muse, mutect2, varscan2
- NTAN1 | c.777T>C p.A259= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99816913; called by muse, mutect2, varscan2
- OPLAH | c.3174C>T p.R1058= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs782104452, COSV101470765; called by muse, mutect2
- OR51A4 | c.240G>A p.L80= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV100985253; called by muse, mutect2, varscan2
- OR5A1 | c.864G>T p.L288= | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as COSV100118358, COSV57376375; called by muse, mutect2, varscan2
- OSR2 | c.180T>C p.N60= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV99882571; called by muse, mutect2, varscan2
- PALM | c.936C>T p.A312= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs142619819, COSV52768494; called by muse, mutect2, varscan2
- PAOX | c.1386C>T p.G462= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs769136556, COSV53373255; called by muse, mutect2, varscan2
- PCDHA2 | c.1533C>T p.H511= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs570971742; called by muse, mutect2, varscan2
- PCDHA6 | c.1971G>A p.P657= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV65343422, COSV65344971; called by muse, mutect2
- PCDHGA12 | c.1302G>A p.T434= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV52744306, COSV99340966, COSV99341962; called by muse, mutect2, varscan2
- PCDHGB4 | c.762C>T p.N254= | Silent (SNP) | VAF 59/247 reads (24%) | catalogued as COSV53899960; called by muse, mutect2, varscan2
- PCNX2 | c.1047C>A p.S349= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV99267499; called by muse, mutect2, varscan2
- PCSK4 | c.720C>T p.I240= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs767882439, COSV99278571; called by muse, mutect2, varscan2
- PER3 | c.2154A>G p.S718= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1392733570, COSV100728343; called by muse, mutect2, varscan2
- PI4KA | c.4665C>T p.A1555= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs147821063; called by muse, varscan2
- PIKFYVE | c.4134G>A p.A1378= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs760133678, COSV52248500; called by muse, mutect2, varscan2
- PLA2G2C | c.207C>T p.Y69= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs550861819, COSV99930279; called by muse, mutect2, varscan2
- PRAMEF15 | c.1254C>T p.P418= | Silent (SNP) | VAF 104/347 reads (30%) | catalogued as rs1234184043, COSV66000144; called by muse, mutect2, varscan2
- PRDM15 | c.2250C>T p.N750= | Silent (SNP) | VAF 65/228 reads (29%) | catalogued as rs372152938; called by muse, mutect2, varscan2
- PRKCB | c.1488G>A p.V496= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV100333949; called by muse, mutect2, varscan2
- PRSS55 | c.795C>T p.Y265= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100153772; called by muse, mutect2, varscan2
- PSME4 | c.3504T>A p.I1168= | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as COSV101122483; called by muse, mutect2, varscan2
- PTPN21 | c.2106G>A p.S702= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs763755289, COSV100161899; called by muse, mutect2, varscan2
- RABL2B | c.63C>T p.N21= | Silent (SNP) | VAF 42/242 reads (17%) | catalogued as rs1224923381, COSV61483798; called by muse, mutect2, varscan2
- RNF213 | c.468G>A p.T156= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1268182657, COSV100173453; called by muse, mutect2, varscan2
- RPL18 | c.237G>A p.T79= | Silent (SNP) | VAF 42/146 reads (29%) | catalogued as rs768483190, COSV99320238; called by muse, mutect2, varscan2
- RWDD4 | c.195C>T p.N65= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs781607096, COSV100419120; called by muse, mutect2, varscan2
- RYR1 | c.5214G>A p.T1738= | Silent (SNP) | VAF 45/129 reads (35%) | catalogued as rs1175081117, COSV62099597; called by muse, mutect2, varscan2
- SATB1 | c.1890G>A p.T630= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs769372550, COSV100113171; called by muse, mutect2, varscan2
- SCNN1G | c.213C>T p.C71= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs748747493, COSV55598732; called by muse, mutect2, varscan2
- SEC31B | c.3252G>A p.A1084= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as rs142754125; called by muse, mutect2, varscan2
- SETX | c.4339T>C p.L1447= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as COSV99809712; called by muse, mutect2, varscan2
- SIM1 | c.1443G>A p.T481= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs777872163, COSV99492339; called by muse, mutect2, varscan2
- SLC12A5 | c.2409C>T p.R803= (on ENST00000454036 / NM_001134771.2; = p.R780= on NM_020708.5) | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV99716006; called by muse, mutect2, varscan2
- SLC43A3 | c.678C>T p.C226= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100725198; called by muse, mutect2, varscan2
- SLC44A2 | c.1998G>A p.T666= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1274489567, COSV100213195; called by muse, mutect2, varscan2
- SMARCD1 | c.333C>G p.V111= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99948023, COSV99948050; called by muse, mutect2, varscan2
- SMTNL1 | c.57G>A p.A19= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs776778790, COSV67699056; called by muse, mutect2, varscan2
- SNX9 | c.1641G>A p.A547= | Silent (SNP) | VAF 96/235 reads (41%) | catalogued as rs1339779649, COSV67585110; called by muse, mutect2, varscan2
- SPIRE1 | c.1608G>A p.L536= (on ENST00000409402 / NM_001128626.2; = p.L522= on NM_020148.3) | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs1192160563, COSV100563638; called by muse, mutect2, varscan2
- SRCIN1 | c.1686C>T p.R562= (on ENST00000621492; = p.R528= on NM_025248.3) | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- SYNE1 | c.14305A>C p.R4769= (on ENST00000367255 / NM_182961.4; = p.R4698= on NM_033071.3) | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as COSV99563518; called by muse, mutect2, varscan2
- TERF1 | c.933A>G p.T311= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52579194; called by muse, mutect2
- TLX3 | c.156G>A p.P52= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs894996817, COSV99740615; called by muse, mutect2
- TMC8 | c.1572C>A p.P524= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV100573730; called by muse, mutect2
- TMEM174 | c.327G>A p.P109= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs770962988, COSV57114477; called by muse, mutect2, varscan2
- TMEM41A | c.123G>A p.S41= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99956604; called by muse, mutect2
- TMPRSS11A | c.822C>T p.Y274= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as rs575446123, COSV58356997; called by muse, mutect2, varscan2
- TRRAP | c.5562C>G p.R1854= (on ENST00000359863 / NM_001244580.1; = p.R1836= on NM_003496.3) | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100722457; called by muse, mutect2, varscan2
- TSC2 | c.1557C>T p.C519= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as COSV99554053; called by muse, mutect2, varscan2
- TSPY2 | c.639T>C p.N213= | Silent (SNP) | VAF 42/307 reads (14%) | catalogued as COSV100289184; called by muse, mutect2, varscan2
- TTN | c.86661T>C p.F28887= (on ENST00000591111; = p.F21463= on NM_003319.4) | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100611840; called by muse, mutect2
- TUSC3 | c.867C>T p.A289= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as rs778689006, COSV101141457; called by muse, mutect2, varscan2
- UNC79 | c.5259G>A p.S1753= (on ENST00000393151 / NM_001346218.2; = p.S1576= on NM_020818.5) | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as rs747494665, COSV56412746; called by muse, mutect2, varscan2
- USP1 | c.2103T>C p.S701= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as COSV99224350; called by muse, varscan2
- USP21 | c.1011C>A p.P337= | Silent (SNP) | VAF 40/147 reads (27%) | catalogued as COSV99237416; called by muse, mutect2, varscan2
- VCAN | c.1395C>T p.G465= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs772684866, COSV54102683; called by muse, mutect2, varscan2
- VPS50 | c.2790G>A p.K930= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as COSV100004805; called by muse, mutect2, varscan2
- WDR62 | c.2214C>T p.C738= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs757339378, COSV99543681; called by muse, mutect2, varscan2
- WDR88 | c.57G>A p.P19= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV50126319; called by muse, mutect2, varscan2
- XYLT1 | c.390C>A p.T130= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99761718; called by muse, mutect2, varscan2
- ZFP30 | c.252T>C p.Y84= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100665896; called by muse, mutect2, varscan2
- ZNF473 | c.2319T>C p.L773= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV99568807; called by muse, mutect2, varscan2
- ZNF672 | c.1308C>T p.L436= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1224279762, COSV60637124; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622858 T>C | 3'Flank (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100247123, COSV57543653; called by muse, mutect2, varscan2
- FBH1 | c.1+4822C>G | Intron (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100758739; called by muse, mutect2, varscan2
- KCNK16 | c.*1G>T | 3'UTR (SNP) | VAF 43/76 reads (57%) | catalogued as COSV100949201; called by muse, mutect2, varscan2
- MACF1 | c.15832-11944C>T | Intron (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- MOCS1 | c.124-86T>C | Intron (SNP) | VAF 10/13 reads (77%) | catalogued as COSV100418610; called by muse, mutect2, varscan2
- PIK3C2B | c.*117_*137del | 3'UTR (DEL) | VAF 11/61 reads (18%) | called by mutect2, pindel, varscan2
- PML | c.1710+812C>T | Intron (SNP) | VAF 44/127 reads (35%) | catalogued as rs201226688; called by muse, mutect2, varscan2
- RPL23AP42 | n.184C>T | RNA (SNP) | VAF 21/89 reads (24%) | catalogued as rs750001762; called by muse, mutect2, varscan2
- SGIP1 | c.99+999del | Intron (DEL) | VAF 8/24 reads (33%) | catalogued as rs745636084, COSV52764888; called by mutect2, varscan2
- SLC7A2 | c.1195+298G>T | Intron (SNP) | VAF 38/96 reads (40%) | catalogued as rs763150887, COSV99134894; called by muse, mutect2, varscan2
- SNORD116-28 | n.21del | RNA (DEL) | VAF 28/107 reads (26%) | catalogued as rs756617362; called by mutect2, pindel, varscan2
- SOHLH1 | c.*680T>C | 3'UTR (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100040164; called by muse, mutect2, varscan2
- TANGO2 | c.56+86G>T | Intron (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100530054; called by muse, mutect2, varscan2
